Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A4S0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A4S0-01A (Primary Tumor).

[page 1 of 2]
Name: [REDACTED] Age/Sex: 1/F Location: [REDACTED]
Acct#: [REDACTED] Unit#: [REDACTED] Status: DIS IN Room/Bed: [REDACTED]
Reg: [REDACTED] Disch: [REDACTED] Att Dr: [REDACTED] M.D.

Specimen: Received: Status: Req#: [REDACTED]
Collected: Sp type: SURGICAL P
Subm Dr: M.D.

PREOPERATIVE DIAGNOSIS

BREAST CA

1CD-0-3
carcinoma, mucinous 8480/3
Site: breast NOS C50.9

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: TOTAL MASTECTOMY; EXCISION OF AXILLARY SENTINEL NODE

fw
10/24/12

TISSUE REMOVED

- A. RIGHT BREAST STITCH AT 12 O'CLOCK
- B. RIGHT SENTINEL NODE #1

GROSS DESCRIPTION

RECEIVED IN 2 PARTS.

A RECEIVED LABELED [REDACTED] RIGHT BREAST STITCH AT 12 O'CLOCK IS A 2041 SIMPLE MASTECTOMY MEASURING 33.5 CM FROM MEDIAL TO LATERAL, 28 CM FROM SUPERIOR TO INFERIOR, AND UP TO 5.5 CM FROM ANTERIOR TO POSTERIOR. THE NIPPLE IS INVERTED WITHIN A 31 X 17 CM SKIN ELLIPSE. A SUTURE DENOTES 12 O'CLOCK. 4 CM LATERAL TO THE NIPPLE AT 9 O'CLOCK IS A LOBULATED RED-TAN GLISTENING MASS MEASURING 2.2 CM FROM SUPERIOR TO INFERIOR, 2 CM FROM ANTERIOR TO POSTERIOR, AND 4.5 CM FROM MEDIAL TO LATERAL. THIS LESION IS 2.5 CM FROM THE DEEP MARGIN. TOWARDS THE LATERAL EDGE THERE IS A 2ND NODULE ADJACENT BY LESS THAN 1 CM MEASURING 1 X 1 X 1 CM. THERE IS A RIBBON CLIP ASSOCIATED WITH THIS AREA. THE REMAINING BREAST TISSUE CONSISTS OF BLAND YELLOW FATTY TISSUE WITH FINE FIBROUS BANDS. A WING CLIP IS IDENTIFIED IN THE LARGER LESION. REPRESENTATIVE SECTIONS ARE SUBMITTED AS FOLLOWS: A1--NIPPLE, A2--DEEP MARGIN TO LARGER LESION, A3--THE MOST LATERAL PORTION OF THE LARGER LESION, A4--THE MOST MEDIAL PORTION OF THE LARGER LESION 4.5 CM FROM A3, A5 THROUGH A7--ADDITIONAL SECTIONS OF LARGER LESION, A8 AND 9--SMALLER SUPERIOR RIBBON CLIP LESION, A10--UPPER INNER QUADRANT 10 CM FROM THE LESION, A11--UPPER OUTER QUADRANT 4 CM FROM LESION, A12--LOWER OUTER QUADRANT 4 CM FROM LESION, A13--LOWER INNER QUADRANT 10 CM FROM LESION.

TISSUE IS TAKEN PER CLINICAL BREAST CARE PROJECT RESEARCH PROTOCOL OF THE LARGER LESION LABELED P1-P5 WITH FROZEN OCT SAMPLES AS MIRROR IMAGES TO P1 AND P2. IN ADDITION A MIRROR IMAGE SECTION OF THE NIPPLE (A1) IS SUBMITTED FROZEN IN OCT ALONG WITH THE 4 RANDOM QUADRANT SECTIONS

[page 2 of 2]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

D.

GROSS DESCRIPTION

(Continued)

A10-A13.

B RECEIVED LABELED [REDACTED] RIGHT SENTINEL NODE #1 HOT AND BLUE COUNT 39252 IS A PORTION OF PINK-TAN TISSUE WITH BLUE COLORATION MEASURING 1.3 X 0.8 X 0.4 CM. THE SPECIMEN IS BISECTED AND SUBMITTED LABELED B.

COMMENT: THIS CASE EXCEEDS THE MAXIMUM CAP/ASCO GUIDELINE OF 48 HOURS FORMALIN FIXATION.

PATH PROCEDURES

PROCEDURES:

88307/2, IMMUNOPEROXIDAS, A BLK/13, BBX X6

FINAL DIAGNOSIS

PART A RIGHT BREAST, SIMPLE MASTECTOMY:

1. INVASIVE MUCINOUS CARCINOMAS (2) GRADE I WITH NUCLEAR GRADE 1 AND LOW MITOTIC INDEX.
2. THE TUMORS MEASURE 4.5 AND 1.0 CM IN GREATEST DIMENSION. THE NIPPLE AND DEEP MARGIN ARE FREE OF NEOPLASM.
3. LYMPHATIC INVASION IS NOT IDENTIFIED.
4. BIOPSY SITE CHANGES WITH CLIPS PRESENT.
5. PROLIFERATIVE FIBROCYSTIC DISEASE WITH CALCIFICATIONS PRESENT.

PART B RIGHT SENTINEL NODE 1: LYMPH NODE (1), NEGATIVE FOR TUMOR BY STEP SECTION AND CYTOKERATIN STAIN.

Mucinous CA 11/11
X2
4.5 $\frac{1}{2}$ 1 cm
O margins
O LVI
Bx2
FCC c/catt

9/15N

Signed _____ Electronically signed by: _____

, M.D.

SIQA Discrepancy		

10/26/12

Source: NCI Genomic Data Commons file 5e1abfd4-6fa8-4a75-9773-0fa348edcbf2 (TCGA-A2-A4S0.0118D9AE-B923-4EEF-BBBC-82D559763FF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).